Gene-level copy-number profile of tumor specimen TCGA-QH-A6CX-01A from TCGA case TCGA-QH-A6CX, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 66.4 years (24,252 days).
Specimen TCGA-QH-A6CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.22e364e9-cb36-44a8-9e87-15bef97986a7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QH-A6CX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6c3d625b-ba53-473a-9aae-af4bb08e895b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,448; copy number 4: 50,207; copy number 5: 154; copy number 6: 1,924; copy number 44: 9; copy number 46: 29; copy number 55: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QH-A6CX-01A-11D-A32A-01): tumor purity 0.66, ploidy 3.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 87 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,626,787–205,134,950, 49 genes, copy number 55: ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2.
- chr7:54,759,348–55,433,742, 9 genes, copy number 44 (within-gene range 4–44): SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr7:56,080,283–56,603,553, 29 genes, copy number 46: PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, AC006970.2, CCNJP1, AC073136.1, AC073136.2, AC093392.1, RNU6-1335P, SEPTIN14P24, CICP8, AC093392.2, RNU6-1052P, AC092423.1, AC092447.7, AC092447.10, AC092447.4, RBM22P3, AC092447.8, NMD3P2, AC092447.3, AC092447.5, VN1R25P, AC092447.2, AC092447.6, AC092447.1, AC092447.9.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
